Somatic mutation profile of tumor specimen MBCProject_0235_T1_WES (aliquot MBCProject_0235_T1_WES_1) from CMI case MBCProject_0235, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0235_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9255635-2bfb-4c3e-8fa8-92ca7df7e69d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0235_SALIVA (Saliva), aliquot MBCProject_0235_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7177b4d-8f99-4d7c-bf77-2776bd9ea029

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Frame Shift Del 5, Silent 4, Intron 3, Splice Site 3, Nonsense Mutation 2, In Frame Del 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 17/82 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 12/316 reads (4%) | catalogued as COSV61375114; called by muse, mutect2
- FAM83B | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs766107564, COSV60924005; called by muse, mutect2, varscan2
- GDF6 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 103/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54623945; called by muse, mutect2, varscan2
- NMRAL1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs779258307; called by muse, mutect2, varscan2
- PANK4 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs749136554; called by muse, mutect2, varscan2
- PGAP1 | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs775283107; called by muse, mutect2, varscan2
- RASGEF1C | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV63177299; called by mutect2, varscan2
- REN | c.692A>T p.D231V | Missense Mutation (SNP) | VAF 48/441 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs755548418; called by muse, mutect2, varscan2
- RPS6KA2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749143875; called by muse, mutect2, varscan2
- TMEM108 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs139116868; called by muse, mutect2, varscan2
- AREL1 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- ATP2B2 | c.865_867del p.L289del | In Frame Del (DEL) | VAF 22/182 reads (12%) | called by mutect2, pindel, varscan2
- BRF2 | c.68_76del p.Q23_Q25del | In Frame Del (DEL) | VAF 18/186 reads (10%) | called by mutect2, pindel
- CNTN6 | c.1946-2A>T p.X649_splice | Splice Site (SNP) | VAF 9/51 reads (18%) | called by muse, varscan2
- CNTNAP4 | c.345T>A p.D115E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHTKD1 | c.606_619del p.F202Lfs*10 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | called by mutect2, pindel, varscan2
- EXOSC9 | c.1275T>A p.S425R | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- HADHB | c.268del p.R90Gfs*8 | Frame Shift Del (DEL) | VAF 69/458 reads (15%) | called by mutect2, pindel, varscan2
- KIAA0586 | c.4044G>T p.Q1348H (on ENST00000619416 / NM_001244190.2; = p.Q1287H on NM_014749.5) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- KIF21B | c.597+1G>A p.X199_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- KLHL41 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LAMA5 | c.6625A>G p.N2209D | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LAMB1 | c.4598T>C p.M1533T | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- NPIPB11 | c.2710C>T p.Q904* | Nonsense Mutation (SNP) | VAF 52/320 reads (16%) | called by muse, varscan2
- OR2L3 | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PARPBP | c.355del p.S119Lfs*25 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | called by mutect2, pindel, varscan2
- PRG2 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- RBL1 | c.2938del p.S980Pfs*35 | Frame Shift Del (DEL) | VAF 14/126 reads (11%) | called by mutect2, pindel, varscan2
- REN | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 49/442 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- SAFB2 | c.1388A>C p.K463T | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- SHANK2 | c.3739C>G p.L1247V | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- SIRT3 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLC24A3 | c.464T>G p.M155R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM121B | c.1619C>G p.A540G | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.503); called by muse, varscan2
- TRIM8 | c.305_330del p.P102Rfs*78 | Frame Shift Del (DEL) | VAF 34/166 reads (20%) | called by mutect2, pindel
- TRPC3 | c.2464-1G>T p.X822_splice (on ENST00000379645 / NM_001366479.2; = p.X749_splice on NM_003305.2) | Splice Site (SNP) | VAF 34/144 reads (24%) | called by mutect2, varscan2
- ZFX | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLG | c.7659A>G p.Q2553= | Silent (SNP) | VAF 89/218 reads (41%) | called by muse, varscan2
- LONRF3 | c.702C>G p.G234= | Silent (SNP) | VAF 17/117 reads (15%) | called by muse, varscan2
- PCDHB13 | c.1596C>T p.G532= | Silent (SNP) | VAF 58/261 reads (22%) | catalogued as COSV53393443; called by muse, mutect2, varscan2
- TMEM132C | c.3246C>T p.I1082= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV59433793; called by muse, mutect2
- DDHD1 | chr14:53152786 C>G | 5'Flank (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- FCRLB | c.575-113del | Intron (DEL) | VAF 6/64 reads (9%) | called by pindel, varscan2
- SLC17A9 | c.59+347C>G | Intron (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.260_268del | RNA (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel*, varscan2*
- TEKT2 | c.283-114T>G | Intron (SNP) | VAF 3/32 reads (9%) | catalogued as rs1245565964; called by muse, mutect2
